Gene-level copy-number profile of tumor specimen ALCH-B6YR-TTP1-A from ALCHEMIST case ALCH-B6YR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.0 years (20,082 days).
Specimen ALCH-B6YR-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 44f78055-99bc-46c5-9db6-33297b04474a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B6YR-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/6a356e86-ac59-4bc6-9794-8ae03960d635

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 57; copy number 2: 6,687; copy number 3: 3,080; copy number 4: 30,508; copy number 5: 5,620; copy number 6: 9,357; copy number 7: 261; copy number 8: 2,767; copy number 9: 2; copy number 10: 21; copy number 14: 7; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–4): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr15:25,174,927–25,203,308, 16 genes (within-gene range 0–3): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 31 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–675,265, 20 genes, copy number 10 (within-gene range 1–10): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6.
- chr1:143,419,625–143,500,512, 7 genes, copy number 14: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr14:99,397,748–99,480,889, 2 genes, copy number 9: SETD3, RNU6-91P.
- chr17:39,868,202–39,877,896, 1 gene, copy number 10: ZPBP2.
- chr21:44,133,610–44,210,114, 1 gene, copy number 17 (within-gene range 4–17): GATD3A.

Autosomal genes at a single copy (total copy number 1): 57. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
